Gene-level copy-number profile of tumor specimen HCM-CSHL-0838-C18-06A from HCMI case HCM-CSHL-0838-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.6 years (21,407 days).
Specimen HCM-CSHL-0838-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 91d5a017-cdcd-42fe-aaca-79399b4890c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0838-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/1f4a4913-0684-4712-8152-bc0d68ed7f98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 7,358; copy number 2: 42,931; copy number 3: 8,050; copy number 4: 10; copy number 5: 1; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:202,660–2,838,823, 46 genes: AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, DLGAP2-AS1, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1.
- chr12:2,740,064–2,775,658, 3 genes: LINC02371, IQSEC3P1, AC092471.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,690,047–246,691,821, 1 gene, copy number 6: AL591848.1.
- chr2:197,569–209,892, 1 gene, copy number 6: AC079779.1.
- chr5:177,782,197–177,794,396, 1 gene, copy number 5 (within-gene range 2–5): AC140125.2.

Autosomal genes at a single copy (total copy number 1): 7,358. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
